Somatic mutation profile of tumor specimen ALCH-B220-TTP1-A (aliquot ALCH-B220-TTP1-A-8-0-D-A76I-36) from ALCHEMIST case ALCH-B220, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.6 years (19,215 days).
Specimen ALCH-B220-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a65f545-75e4-44b1-a5f4-6a36741aa166.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B220-NB1-A (Blood Derived Normal), aliquot ALCH-B220-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a4887b1-0b12-4b35-b8c4-693ee589206f

The open-access MAF lists 106 somatic variants for this specimen: 70 protein-altering or splice-affecting, 19 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Intron 11, Frame Shift Del 5, Nonsense Mutation 4, RNA 3, 3'Flank 2, Splice Region 2, In Frame Ins 1, Splice Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2317_2319dup p.H773dup | In Frame Ins (INS) | VAF 40/324 reads (12%) | hotspot (GDC flag); catalogued as rs1554350381, COSV51800933, COSV51820458; ClinVar: uncertain significance; called by mutect2, pindel
- AC011448.1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs202057353, COSV99364389; called by muse, mutect2, varscan2
- ALDH3A2 | c.1231C>A p.H411N | Missense Mutation (SNP) | VAF 90/562 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM993316; called by muse, mutect2, varscan2
- APLP1 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1329940464; called by muse, mutect2, varscan2
- CHD6 | c.7690G>C p.V2564L | Missense Mutation (SNP) | VAF 57/389 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs762472528; called by muse, mutect2, varscan2
- EPHA5 | c.2874A>T p.E958D | Missense Mutation (SNP) | VAF 32/387 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV56642654; called by muse, mutect2
- KCTD13 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs779703694, COSV100442184; called by muse, mutect2, varscan2
- MUC16 | c.38187_38188del p.R12729Sfs*47 | Frame Shift Del (DEL) | VAF 32/301 reads (11%) | catalogued as rs1284025808; called by pindel, varscan2
- NOS1AP | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 155/1090 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV62640188; called by muse, mutect2, varscan2
- PHF8 | c.383G>A p.R128Q (on ENST00000357988 / NM_001184896.1; = p.R92Q on NM_015107.3) | Missense Mutation (SNP) | VAF 79/533 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1033986927; called by muse, mutect2, varscan2
- PHLDB2 | c.2279C>G p.S760C (on ENST00000393925 / NM_001134439.2; = p.S717C on NM_145753.2) | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV67311281; called by muse, mutect2, varscan2
- PLXNB2 | c.3926G>A p.R1309Q | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1057253566; called by muse, mutect2, varscan2
- RIMS1 | c.5030C>T p.S1677F | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99324055; called by mutect2, varscan2
- RPS6KB1 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.867); catalogued as rs1033258409, COSV56677478; called by muse, mutect2, varscan2
- SDK1 | c.953G>T p.S318I | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV101269411; called by muse, mutect2
- TCHH | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs755360885; called by muse, mutect2, varscan2
- UBE2T | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 66/562 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs1034241281; called by muse, mutect2, varscan2
- USH2A | c.5273A>G p.N1758S | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs767820497, COSV100234841, COSV56342971, COSV56374871; called by muse, mutect2, varscan2
- USH2A | c.4414C>A p.P1472T | Missense Mutation (SNP) | VAF 58/588 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV56435740; called by muse, mutect2, varscan2
- ZEB2 | c.2011T>C p.S671P | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV57956862; called by muse, mutect2, varscan2
- ZNF493 | c.-129A>G | Splice Region (SNP) | VAF 4/39 reads (10%) | catalogued as rs1353785151; called by muse, mutect2
- ALOXE3 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 92/742 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ANXA3 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP31 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 118/654 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ARHGAP31 | c.1636A>G p.T546A | Missense Mutation (SNP) | VAF 100/744 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRIP1 | c.3008C>G p.S1003* | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | called by muse, mutect2, varscan2
- BRSK2 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CADPS | c.2923G>A p.D975N | Missense Mutation (SNP) | VAF 57/355 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CCDC17 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC27 | c.1441A>G p.M481V | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CCM2 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 65/584 reads (11%) | called by muse, mutect2
- CDIN1 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CECR2 | c.1024_1037del p.L342Efs*85 (on ENST00000342247 / NM_001290047.2; = p.L179Efs*65 on NM_001290046.1) | Frame Shift Del (DEL) | VAF 46/550 reads (8%) | called by mutect2, pindel
- CFH | c.1828C>A p.Q610K | Missense Mutation (SNP) | VAF 64/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CIB3 | c.68C>G p.T23R | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CRMP1 | c.215T>A p.V72D | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2
- CTAGE1 | c.2140_2148del p.R714_P716del | In Frame Del (DEL) | VAF 62/408 reads (15%) | called by mutect2, pindel, varscan2
- CYLC1 | c.1666A>G p.K556E | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- DENND2A | c.2368T>C p.Y790H | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUOX1 | c.4536C>T p.V1512= | Splice Region (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- DUS1L | c.813_842+1del p.X271_splice | Splice Site (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- E2F2 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GARRE1 | c.1192C>G p.Q398E | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GPD2 | c.1454_1473del p.Q485Rfs*12 | Frame Shift Del (DEL) | VAF 55/468 reads (12%) | called by mutect2, pindel
- HEPH | c.1903G>A p.D635N (on ENST00000343002; = p.D368N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/558 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- KALRN | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- KCNK17 | c.173A>C p.D58A | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP1B | c.2967G>T p.K989N | Missense Mutation (SNP) | VAF 64/454 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- MRPL19 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 40/302 reads (13%) | called by muse, mutect2, varscan2
- MYBPC3 | c.2750T>A p.V917E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- MYO7A | c.6373T>G p.F2125V | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYOD1 | c.214del p.A72Pfs*51 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | called by mutect2, pindel, varscan2
- PDSS1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PEX12 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POU4F2 | c.777G>C p.E259D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PPP5C | c.705G>C p.E235D | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PYGL | c.2142G>C p.M714I | Missense Mutation (SNP) | VAF 106/701 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- RGS12 | c.3235A>C p.S1079R | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RPS6KA6 | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2
- RPS6KA6 | c.1232del p.P411Qfs*5 | Frame Shift Del (DEL) | VAF 20/137 reads (15%) | called by mutect2, pindel*
- RTN2 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- SEMA7A | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SPATA31D1 | c.3223C>G p.L1075V | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SVIL | c.3722G>C p.R1241T (on ENST00000355867 / NM_021738.3; = p.R815T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TAAR2 | c.736T>G p.L246V (on ENST00000367931 / NM_001033080.1; = p.L201V on NM_014626.3) | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TBX5 | c.1516C>A p.H506N | Missense Mutation (SNP) | VAF 89/473 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TMEM214 | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZBTB49 | c.1526G>T p.C509F | Missense Mutation (SNP) | VAF 20/519 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF443 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF689 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP3B2 | c.2133T>A p.S711= | Silent (SNP) | VAF 74/449 reads (16%) | called by muse, mutect2, varscan2
- ATP2B1 | c.2556C>T p.I852= | Silent (SNP) | VAF 99/518 reads (19%) | called by muse, mutect2, varscan2
- CRACD | c.2307C>T p.L769= | Silent (SNP) | VAF 63/402 reads (16%) | called by muse, mutect2, varscan2
- DMTF1 | c.744A>T p.T248= | Silent (SNP) | VAF 75/430 reads (17%) | called by muse, mutect2, varscan2
- GRB7 | c.381G>C p.V127= | Silent (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- HSPA5 | c.801C>T p.I267= | Silent (SNP) | VAF 37/201 reads (18%) | catalogued as rs1286774050; called by muse, mutect2, varscan2
- JPH2 | c.2064C>T p.A688= | Silent (SNP) | VAF 102/563 reads (18%) | catalogued as rs1250890043; called by muse, mutect2, varscan2
- KCNE4 | c.468G>A p.L156= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1448509560; called by muse, mutect2, varscan2
- KRT81 | c.1506C>T p.C502= | Silent (SNP) | VAF 47/283 reads (17%) | catalogued as rs759545377; called by muse, mutect2, varscan2
- KRT9 | c.120C>T p.G40= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs373248434; called by muse, mutect2
- LAT | c.345G>A p.A115= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs774578428, COSV100209244; called by muse, mutect2, varscan2
- LRP1 | c.1506G>A p.R502= | Silent (SNP) | VAF 9/306 reads (3%) | catalogued as rs1449186081, COSV54507270; called by muse, mutect2
- NEB | c.12819G>C p.L4273= | Silent (SNP) | VAF 56/341 reads (16%) | called by muse, mutect2, varscan2
- P2RX6 | c.600C>T p.I200= | Silent (SNP) | VAF 19/384 reads (5%) | catalogued as COSV100298634; called by muse, mutect2
- PLCB2 | c.2358C>T p.S786= | Silent (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- PNLIP | c.534T>C p.A178= | Silent (SNP) | VAF 54/359 reads (15%) | called by muse, mutect2, varscan2
- SLC28A2 | c.1707C>T p.F569= | Silent (SNP) | VAF 10/309 reads (3%) | called by muse, mutect2
- SORCS2 | c.435G>C p.A145= | Silent (SNP) | VAF 49/190 reads (26%) | called by muse, mutect2, varscan2
- TG | c.2826T>C p.I942= | Silent (SNP) | VAF 226/728 reads (31%) | called by muse, mutect2, varscan2
- AC004947.2 | n.145G>C | RNA (SNP) | VAF 47/257 reads (18%) | called by muse, mutect2, varscan2
- AC084082.1 | n.354-9C>T | Intron (SNP) | VAF 20/604 reads (3%) | catalogued as rs919024987; called by muse, mutect2
- AC132217.2 | c.*46+1218G>A | Intron (SNP) | VAF 62/330 reads (19%) | called by muse, mutect2, varscan2
- CACNB1 | c.628+452C>G | Intron (SNP) | VAF 26/225 reads (12%) | called by muse, mutect2, varscan2
- CCNYL2 | n.946C>T | RNA (SNP) | VAF 11/74 reads (15%) | catalogued as rs1325540157; called by muse, mutect2, varscan2
- CEP85 | c.1744-18G>C | Intron (SNP) | VAF 41/271 reads (15%) | called by muse, mutect2, varscan2
- CHTF8 | chr16:69118528 G>C | 3'Flank (SNP) | VAF 213/643 reads (33%) | catalogued as COSV99544584; called by muse, mutect2, varscan2
- DUSP18 | c.-77-1431G>A | Intron (SNP) | VAF 35/247 reads (14%) | catalogued as rs753549425; called by muse, mutect2, varscan2
- GRAMD1C | c.953-2592C>A | Intron (SNP) | VAF 72/437 reads (16%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.2071G>A | RNA (SNP) | VAF 47/270 reads (17%) | catalogued as rs757545487; called by muse, mutect2, varscan2
- LILRB2 | c.1360+43G>A | Intron (SNP) | VAF 14/92 reads (15%) | called by muse, varscan2
- PIM2 | c.-10C>T | 5'UTR (SNP) | VAF 37/237 reads (16%) | catalogued as rs1557045608, COSV99332359; called by muse, mutect2, varscan2
- SEPTIN7 | c.62-1275_62-1274del | Intron (DEL) | VAF 14/130 reads (11%) | called by pindel, varscan2
- SLC25A10 | c.378-40T>G | Intron (SNP) | VAF 10/75 reads (13%) | called by muse, varscan2
- SMIM12 | chr1:34855287 G>A | 3'Flank (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- TAF1B | c.117+811G>C | Intron (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
- ZNF841 | c.-77-8482A>G | Intron (SNP) | VAF 43/376 reads (11%) | called by muse, mutect2, varscan2
